Gene-level copy-number profile of tumor specimen C3L-09775-01 (profiled together with C3L-09775-02, C3L-09775-03) from CPTAC case C3L-09775, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 65.1 years (23,768 days).
Specimen C3L-09775-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c751727-97b5-4cf1-b292-51bd64e8e2bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09775-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/e8677ada-2aa8-4328-b743-a816f938eb95

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 535; copy number 1: 226; copy number 2: 7,517; copy number 3: 27,513; copy number 4: 15,581; copy number 5: 1,100; copy number 6: 4,230; copy number 7: 2,174; copy number 8: 9; copy number 9: 1; copy number 11: 3; copy number 61: 1; copy number 83: 1; copy number 119: 1; copy number 150: 2; copy number 172: 2; copy number 224: 7; copy number 300: 1; copy number 383: 3.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–3): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–2): RN7SL5P.
- chr18:45,034–73,545, 3 genes: AP001005.1, TUBB8B, AP001005.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,205 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:103,926,567–104,226,678, 3 genes, copy number 8: AL136455.1, AC092506.1, FTLP17.
- chr1:143,419,625–143,450,245, 3 genes, copy number 11: AC239859.5, RNA5SP533, AC239859.3.
- chr1:143,811,359–143,825,837, 1 gene, copy number 8: AC239798.1.
- chr1:174,022,509–174,160,165, 3 genes, copy number 7 (within-gene range 4–7): LINC02776, RPL30P1, RABGAP1L-DT.
- chr2:241,881,363–242,078,722, 1 gene, copy number 8 (within-gene range 4–9): LINC01237.
- chr2:241,970,683–242,088,457, 6 genes, copy number 7–9: LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2.
- chr7:66,376,044–118,951,259, 909 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:69,987,415–145,066,685, 1,146 genes, copy number 7 (broad region; genes not listed).
- chr13:72,453,902–81,302,407, 115 genes, copy number 7 (broad region; genes not listed).
- chr18:48,475,487–48,963,941, 12 genes, copy number 150–383: RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1.
- chr18:75,696,044–76,015,861, 4 genes, copy number 61–300: LINC01898, AC021506.1, AC021506.2, AC090457.1.
- chr18:76,751,305–76,759,866, 2 genes, copy number 172: CCND3P2, AC139085.1.

Autosomal genes at a single copy (total copy number 1): 226. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
